Surgical pathology report (de-identified scan), TCGA case TCGA-E7-A6ME, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Asterand, specimen TCGA-E7-A6ME-01A (Primary Tumor).

Patient ID:

Surgical Date:

Gross Description: Tumor is located in anterior wall, nearby of bladder neck. It is invasive and protruded, ill - margins with 4x3x1cm in size, necrotic, soft and gray surface.

Microscopic Description: Tumor is density. Tumor cells are hyperplastic to arrange to form sheets or nest or groups or cords. Tumor cells have moderate and eosinophilic or clear cytoplasm. Nuclei are enlarged and variability in shape and size, irregular nuclear membranes, nucleoli and abnormal chromatin patterns. Mitoses are present. Tumor invades in muscle propria and vessel, necrotic

Diagnosis Details: Infiltrating urothelial carcinoma, high-grade, infiltrating in outer muscularis propria

Comments:

Formatted Path Reports: BLADDER TISSUE CHECKLIST

Specimen type: Cystectomy

Tumor site: Bladder

Tumor size: 4 x 3 x 1 cm

Tumor features: None specified

Histologic type: Transitional cell carcinoma

Histologic grade: Poorly differentiated

Tumor extent: Deep muscle

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-O-3
C67.3
path Carcinoma, urothelial NOS
8/20/13
Carcinoma, transitional cell NOS
8/20/13
Site: Anterior wall of
Bladder C67.3
8/20/13

Qual/Syn/chronous Primary noted		

Source: NCI Genomic Data Commons file 270b7e07-5798-467d-a4ac-db31269d6201 (TCGA-E7-A6ME.491F83D0-4A70-4076-9BDF-1A266925116C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).